CCDI case PBBLGZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/2da4fb2d-0a4c-4815-adaa-b45f8a056355

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Choroid; Age at diagnosis: 0.4 years (152 days).

Biospecimens (3 samples)
- Sample 0DBZ50: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBZ5A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBZ5F: Tissue type: Tumor; Specimen type: Solid Tissue.
